Somatic mutation profile of tumor specimen TCGA-IQ-A61G-01A (aliquot TCGA-IQ-A61G-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.7 years (21,066 days).
Specimen TCGA-IQ-A61G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 939fe60f-62b9-4961-9ba9-a21ca2a5fd35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61G-10A (Blood Derived Normal), aliquot TCGA-IQ-A61G-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab7efc69-d7b2-4197-8ce1-ca7c0f8c67c1

The open-access MAF lists 143 somatic variants for this specimen: 107 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 35, Nonsense Mutation 9, Splice Site 3, Frame Shift Del 3, In Frame Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 39/49 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309275, COSV63309367; called by muse, mutect2, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 54/66 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1913T>C p.L638S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758265086, COSV99445844; called by muse, mutect2, varscan2
- ACTN4 | c.2514G>T p.E838D | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99399790; called by muse, mutect2
- ACTR6 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51841062; called by muse, mutect2, varscan2
- ADAM21 | c.1336T>A p.C446S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960514, COSV99961295; called by muse, mutect2, varscan2
- ADGRL3 | c.737G>C p.R246T (on ENST00000506720 / NM_001322402.2; = p.R178T on NM_015236.6) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101546862, COSV72273146; called by muse, mutect2, varscan2
- AHCTF1 | c.2197G>T p.V733L (on ENST00000366508; = p.V707L on NM_015446.5) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100403125; called by muse, mutect2, varscan2
- ALK | c.1680G>C p.L560F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.194); catalogued as COSV66560279, COSV66561893; called by muse, mutect2, varscan2
- ALPP | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs753036535, COSV67395940; called by muse, mutect2, varscan2
- AOPEP | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV99467611; called by muse, mutect2, varscan2
- ATG2B | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100737712; called by muse, mutect2, varscan2
- ATP13A4 | c.3410T>G p.M1137R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100710092; called by muse, mutect2, varscan2
- ATP2A1 | c.1730T>G p.V577G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV100837083; called by muse, mutect2, varscan2
- CACNA1D | c.3223C>T p.R1075W (on ENST00000350061 / NM_001128840.3; = p.R1095W on NM_000720.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777765883, COSV99856641; called by muse, mutect2, varscan2
- CARMIL3 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765102810, COSV57726706; called by muse, mutect2
- CCDC66 | c.1699A>T p.K567* (on ENST00000394672 / NM_001353147.1; = p.K533* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100413686; called by muse, mutect2, varscan2
- CCNL2 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.306); catalogued as COSV101275644, COSV68766173; called by muse, mutect2, varscan2
- CDCA2 | c.387+1G>T p.X129_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99648380; called by muse, mutect2, varscan2
- CDH7 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.194); catalogued as COSV100541457; called by muse, mutect2, varscan2
- CDK14 | c.697G>A p.V233M (on ENST00000380050 / NM_001287135.2; = p.V215M on NM_012395.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56052880, COSV99723792; called by muse, mutect2, varscan2
- CEP104 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.455); catalogued as rs765557028, COSV100986376, COSV65512417; called by muse, mutect2, varscan2
- CIR1 | c.873G>C p.R291S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100564868; called by muse, mutect2, varscan2
- COL6A3 | c.2801G>A p.S934N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796250; called by muse, mutect2, varscan2
- COLEC10 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773596648, COSV60520914; called by muse, mutect2, varscan2
- CRBN | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs370224981; called by muse, mutect2, varscan2
- CWC27 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs1444332691, COSV101126446; called by muse, mutect2
- CWH43 | c.785T>G p.L262W | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as COSV99892829; called by muse, mutect2, varscan2
- DACT1 | c.916T>C p.C306R | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60023247; called by muse, mutect2, varscan2
- DCAF5 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs369685131; called by muse, mutect2
- DCLRE1B | c.1079G>T p.S360I | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1203745071, COSV100849766; called by muse, mutect2, varscan2
- DRD1 | c.150G>C p.R50S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as CM086310, COSV101192375; called by muse, mutect2, varscan2
- DSCAM | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs867503405, COSV101258784; called by muse, mutect2, varscan2
- EHMT2 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV100977121; called by muse, mutect2
- EPN1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99321563; called by muse, mutect2, varscan2
- ERBB2 | c.2962G>A p.V988I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99506740; called by muse, mutect2, varscan2
- FAM209B | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs759935728, COSV64915053; called by muse, mutect2, varscan2
- FAM47B | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1372835096, COSV100264066; called by muse, mutect2, varscan2
- FYTTD1 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99611345; called by muse, mutect2, varscan2
- GDF6 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99747637; called by muse, mutect2, varscan2
- GPR17 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs369485456; called by muse, mutect2, varscan2
- GRM8 | c.2587G>T p.A863S | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV100280838; called by muse, mutect2, varscan2
- GRM8 | c.1688A>T p.N563I | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV100280840; called by muse, mutect2, varscan2
- GSTM4 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100263981; called by muse, mutect2, varscan2
- GSTM4 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100263984; called by muse, mutect2, varscan2
- H2BC13 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100704320; called by muse, mutect2, varscan2
- HAUS5 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774820509, COSV52548956; called by muse, mutect2, varscan2
- HOXD3 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056813916, COSV50879384, COSV99979896; called by muse, mutect2, varscan2
- HROB | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV99809105; called by muse, mutect2, varscan2
- IGLV1-50 | c.103del p.Q35Rfs*82 | Frame Shift Del (DEL) | VAF 57/183 reads (31%) | catalogued as rs775809903; called by mutect2, pindel, varscan2
- KCNMB3 | c.554C>G p.P185R | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); catalogued as COSV99834060; called by muse, mutect2, varscan2
- KDM2B | c.883T>A p.C295S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100997197; called by muse, mutect2, varscan2
- KIF16B | c.2783T>G p.F928C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100733795, COSV61700989; called by muse, mutect2, varscan2
- KIR2DL3 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 204/564 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV100667578; called by muse, varscan2
- LARP1B | c.2692A>T p.I898L | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99217784; called by muse, mutect2
- LRRC55 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs374511641, COSV73006823; called by muse, mutect2, varscan2
- LRRC7 | c.4397G>T p.G1466V (on ENST00000651989 / NM_001370785.2; = p.G1386V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV99224576; called by muse, mutect2, varscan2
- LY75-CD302 | c.5134_5136del p.E1712del | In Frame Del (DEL) | VAF 37/64 reads (58%) | catalogued as rs779639279; called by pindel, varscan2
- MAGEL2 | c.2582C>G p.A861G | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100045740, COSV58566335; called by muse, mutect2, varscan2
- ME2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs16952692, COSV100360572; called by muse, mutect2, varscan2
- MKRN2 | c.1018G>T p.G340* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV99311895; called by muse, mutect2
- MOCS1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs960220783, COSV99224645; called by muse, mutect2, varscan2
- MOCS1 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV99224646; called by muse, mutect2, varscan2
- MST1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as rs771296103, COSV56537681; called by muse, mutect2, varscan2
- MYOCD | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480273905, COSV100590200; called by muse, mutect2, varscan2
- NAP1L2 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV100999181; called by muse, mutect2, varscan2
- NT5C3B | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 144/176 reads (82%) | catalogued as COSV99505050; called by muse, mutect2
- NUAK2 | c.1638C>A p.D546E | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as rs376539362, COSV100903967; called by muse, mutect2, varscan2
- ODF3L1 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.578); catalogued as COSV100150689; called by muse, mutect2, varscan2
- OR5I1 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100041210; called by muse, mutect2, varscan2
- PAPSS1 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99491791; called by muse, mutect2, varscan2
- PAXBP1 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1482017934, COSV99269029; called by muse, mutect2, varscan2
- PCDH1 | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538786315, COSV99745505; called by muse, mutect2, varscan2
- PCDH15 | c.4536A>T p.K1512N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100215475; called by muse, mutect2, varscan2
- PCDH17 | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100931437; called by muse, mutect2, varscan2
- PHIP | c.1964A>G p.D655G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99243442; called by muse, mutect2, varscan2
- PIP5K1B | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1385647780, COSV99597993; called by muse, mutect2, varscan2
- PLCB1 | c.2185G>C p.E729Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100569417, COSV62051786; called by muse, mutect2, varscan2
- POSTN | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123251; called by muse, mutect2, varscan2
- RALGAPA1 | c.1902T>A p.N634K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV99353348; called by muse, mutect2, varscan2
- RBL2 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100043312; called by muse, mutect2, varscan2
- RBM5 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100762149; called by muse, mutect2, varscan2
- RGS18 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV66507111, COSV66508225; called by muse, mutect2, varscan2
- RNF113B | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57436370; called by muse, mutect2, varscan2
- RPGRIP1 | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99250473; called by muse, mutect2, varscan2
- RRAS | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs779695706, COSV99881966; called by muse, mutect2, varscan2
- SCN3A | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99325703; called by muse, mutect2, varscan2
- SERPINA9 | c.1051-1G>T p.X351_splice | Splice Site (SNP) | VAF 32/59 reads (54%) | catalogued as COSV100097904; called by muse, mutect2, varscan2
- SLC24A4 | c.932T>A p.I311N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV100104270; called by muse, mutect2, varscan2
- SMG8 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99958677; called by muse, mutect2
- SPTA1 | c.3494G>A p.W1165* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100934283; called by muse, mutect2, varscan2
- SRRM4 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99937769; called by muse, mutect2, varscan2
- SUFU | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100882871; called by muse, mutect2, varscan2
- TECRL | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV101168470; called by muse, mutect2, varscan2
- TFCP2 | c.10del p.A4Lfs*2 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV56936499; called by mutect2, pindel, varscan2
- UBE3A | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV51670426, COSV99216764; called by muse, mutect2, varscan2
- UNC79 | c.7069T>C p.F2357L (on ENST00000393151 / NM_001346218.2; = p.F2180L on NM_020818.5) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99825929; called by muse, mutect2, varscan2
- USP44 | c.451T>C p.W151R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV99311599; called by muse, mutect2, varscan2
- VPS13B | c.3021G>T p.K1007N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.638); catalogued as COSV100660889, COSV62161015; called by muse, mutect2, varscan2
- XIRP2 | c.112C>T p.L38F (on ENST00000628543; = p.L213F on NM_152381.6) | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV99738674; called by muse, mutect2, varscan2
- XKR4 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100530919; called by muse, mutect2, varscan2
- ZNF491 | c.589A>C p.N197H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.477); catalogued as COSV100021799; called by muse, mutect2, varscan2
- ZNF835 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101606263; called by muse, mutect2, varscan2
- ZNF85 | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100059477; called by muse, mutect2, varscan2
- GALNT16 | c.1532_1539+3delinsC p.X511_splice | Splice Site (DEL) | VAF 12/80 reads (15%) | called by pindel, varscan2*
- P2RY8 | c.70del p.V24Wfs*39 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- TIAM2 | c.4051dup p.S1351Ffs*24 (on ENST00000529824; = p.S1322Ffs*24 on NM_012454.3) | Frame Shift Ins (INS) | VAF 34/105 reads (32%) | called by mutect2, pindel, varscan2
- ANO1 | c.762G>A p.L254= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as COSV100303703; called by muse, mutect2
- AOX1 | c.2319G>A p.V773= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV101021745; called by muse, mutect2, varscan2
- B3GAT3 | c.684C>A p.G228= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99605716; called by muse, mutect2, varscan2
- BMF | c.162C>T p.H54= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs753708944, COSV99590355; called by muse, mutect2, varscan2
- CCNB3 | c.3099A>G p.L1033= | Silent (SNP) | VAF 39/55 reads (71%) | catalogued as COSV99328467; called by muse, mutect2, varscan2
- CDCA7L | c.81T>C p.V27= | Silent (SNP) | VAF 31/281 reads (11%) | catalogued as COSV100650959; called by muse, mutect2, varscan2
- CFAP61 | c.3243G>A p.A1081= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1472296292, COSV55620127; called by muse, mutect2, varscan2
- CHAF1B | c.900G>T p.L300= | Silent (SNP) | VAF 77/222 reads (35%) | catalogued as COSV100023345; called by muse, mutect2, varscan2
- COG7 | c.1719G>A p.R573= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100207371; called by muse, mutect2, varscan2
- CYB5R4 | c.1437G>A p.L479= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100859635; called by muse, mutect2, varscan2
- CYFIP1 | c.1317G>A p.T439= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as rs765112283; called by muse, mutect2, varscan2
- DNAH3 | c.5502C>T p.P1834= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs757061347, COSV99765044; called by muse, mutect2, varscan2
- EIF2AK3 | c.3135G>A p.Q1045= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100303451; called by muse, mutect2, varscan2
- FGG | c.741T>C p.T247= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100271695; called by muse, mutect2, varscan2
- FRAS1 | c.8406C>T p.S2802= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs771154796, COSV99348383; called by muse, mutect2, varscan2
- GCC2 | c.3099G>A p.L1033= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100565255; called by muse, mutect2, varscan2
- GRM3 | c.1617C>T p.Y539= | Silent (SNP) | VAF 82/155 reads (53%) | catalogued as COSV100862131; called by muse, mutect2, varscan2
- KRT1 | c.1893C>T p.S631= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as COSV52870502; called by muse, mutect2
- LAMC1 | c.2709G>A p.G903= | Silent (SNP) | VAF 64/109 reads (59%) | catalogued as rs373706219; called by muse, mutect2, varscan2
- NCKAP5L | c.2484T>A p.P828= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100258353; called by muse, mutect2, varscan2
- NRG3 | c.177G>C p.V59= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100930748; called by muse, mutect2, varscan2
- OR2W1 | c.720C>G p.T240= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as COSV101013895, COSV101013923; called by muse, mutect2, varscan2
- OR4K15 | c.831A>T p.P277= (on ENST00000305051; = p.P253= on NM_001005486.1) | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100520972; called by muse, mutect2, varscan2
- PEX5L | c.1368G>T p.G456= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV55846479, COSV99827953; called by muse, mutect2, varscan2
- PLA2G4C | c.75T>G p.L25= | Silent (SNP) | VAF 106/215 reads (49%) | catalogued as COSV100843841; called by muse, mutect2, varscan2
- PRAMEF20 | c.924A>G p.S308= | Silent (SNP) | VAF 59/472 reads (13%) | called by muse, mutect2, varscan2
- RASAL1 | c.960G>A p.G320= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs745591829, COSV55656876; called by muse, mutect2, varscan2
- SALL3 | c.3402G>A p.T1134= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs780742305, COSV101609936; called by muse, mutect2, varscan2
- SCAF4 | c.2640C>T p.P880= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV99531997; called by muse, mutect2, varscan2
- SLITRK4 | c.1410C>T p.D470= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV100567158; called by muse, mutect2, varscan2
- STAG3 | c.3303C>T p.S1101= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100116630; called by muse, mutect2, varscan2
- THBD | c.1524G>T p.P508= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV101001841; called by muse, mutect2, varscan2
- VWCE | c.2505A>G p.P835= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV100075581; called by muse, mutect2, varscan2
- ZFHX4 | c.369C>T p.D123= | Silent (SNP) | VAF 64/112 reads (57%) | catalogued as rs763309092, COSV51476299, COSV99256473; called by muse, mutect2, varscan2
- ZNF225 | c.819C>T p.S273= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as COSV99489284; called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1654T>G | Intron (SNP) | VAF 57/527 reads (11%) | catalogued as COSV99195416; called by muse, mutect2, varscan2
